Gene-level copy-number profile of tumor specimen TCGA-D1-A0ZP-01A from TCGA case TCGA-D1-A0ZP, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IVA; Tumor grade: G3; Age at diagnosis: 59.1 years (21,581 days).
Specimen TCGA-D1-A0ZP-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-UCEC.bd245adc-270d-4707-9153-36ff2b262a53.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-D1-A0ZP-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 815 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/dc094de5-33dd-4159-bf15-41dcd5181f21

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 3,937; copy number 2: 47,117; copy number 3: 5,701; copy number 4: 2,160; copy number 5: 199; copy number 6: 250; copy number 7: 156; copy number 8: 30; copy number 11: 60; copy number 13: 38; copy number 18: 26; copy number 19: 134.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-D1-A0ZP-01A-21D-A10L-01): tumor purity 0.75, ploidy 2.19, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 893 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:70,075,014–70,302,090, 13 genes, copy number 7: RN7SL470P, PCBP1, AC016700.1, MRPL36P1, LINC01816, C2orf42, TIA1, MIR1285-2, RPL39P15, PCYOX1, SNRPG, FAM136A, AC022201.2.
- chr2:158,795,317–158,935,985, 6 genes, copy number 5 (within-gene range 3–5): DAPL1, AC064843.1, OR7E89P, OR7E28P, OR7E90P, RNU2-21P.
- chr2:159,003,975–159,004,320, 1 gene, copy number 5: BTF3L4P2.
- chr10:58,869,184–61,821,246, 30 genes, copy number 8: RN7SKP196, LINC00844, RPLP1P10, TRAF6P1, PHYHIPL, FAM13C, AC025038.1, AL355474.1, MRPL50P4, AC026391.1, SLC16A9, MRLN, CCDC6, LINC01553, ANK3, AL592430.1, Y_RNA, AL592430.2, ARL4AP1, ANK3-DT, CDK1, RHOBTB1, RNU2-72P, LINC00845, TMEM26, TMEM26-AS1, AL356952.1, CABCOCO1, AL451049.1, LINC02625.
- chr10:73,065,126–75,373,500, 85 genes, copy number 11–18 (within-gene range 2–18) (broad region; genes not listed).
- chr10:75,288,333–75,288,682, 1 gene, copy number 18: AC010997.1.
- chr17:19,678,288–22,706,703, 132 genes, copy number 7 (broad region; genes not listed).
- chr17:46,721,582–47,054,569, 11 genes, copy number 7 (within-gene range 2–7): RPS7P11, WNT3, WNT9B, LINC01974, AC005670.1, RNU6ATAC3P, GOSR2, AC005670.2, MIR5089, RPRML, LRRC37A17P.
- chr17:50,781,306–60,666,280, 216 genes, copy number 6 (broad region; genes not listed).
- chr17:60,696,313–60,900,185, 6 genes, copy number 6: RN7SL606P, AC110602.1, Y_RNA, KRT18P61, HMGN1P28, RN7SL448P.
- chr17:62,626,031–70,629,265, 220 genes, copy number 5–6 (broad region; genes not listed).
- chr20:43,540,171–48,494,309, 172 genes, copy number 13–19 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 3,937. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
